Gene-level copy-number profile of tumor specimen TCGA-SW-A7EB-01A from TCGA case TCGA-SW-A7EB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.1 years (16,475 days).
Specimen TCGA-SW-A7EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f78a4ce6-8032-4447-b15f-76b2306f0273.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SW-A7EB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f449be23-2c08-49ff-a6a2-d64f42770184

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 9,729; copy number 2: 33,678; copy number 3: 12,596; copy number 4: 2,727; copy number 5: 370; copy number 6: 412; copy number 7: 43; copy number 8: 30; copy number 9: 122; copy number 11: 28; copy number 12: 36; copy number 13: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SW-A7EB-01A-11D-A34T-01): tumor purity 0.22, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:75,742,740–75,743,755, 1 gene: AL731568.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,076 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–11,520,175, 228 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:11,406,955–11,414,078, 1 gene, copy number 5 (within-gene range 4–5): AC004160.2.
- chr8:78,760,142–100,776,865, 369 genes, copy number 5–9 (broad region; genes not listed).
- chr8:111,376,639–112,148,825, 5 genes, copy number 7: LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr8:112,446,575–112,457,993, 1 gene, copy number 11: AC024996.1.
- chr8:113,376,669–115,809,673, 10 genes, copy number 7 (within-gene range 3–7): AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1.
- chr8:118,620,498–135,742,495, 258 genes, copy number 5–13 (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 5: AC103955.1.
- chr12:55,434,734–55,585,471, 1 gene, copy number 6 (within-gene range 3–6): AC122685.1.
- chr12:55,492,378–58,813,060, 176 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:95,217,746–95,791,189, 15 genes, copy number 6 (within-gene range 1–6): VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4.
- chr20:60,087,826–61,083,750, 9 genes, copy number 5 (within-gene range 4–5): MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718.
- chr20:61,267,525–61,370,855, 2 genes, copy number 5: AL365229.1, BX640515.1.

Autosomal genes at a single copy (total copy number 1): 7,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
